Somatic mutation profile of tumor specimen PCProject_0392_T2_WES (aliquot PCProject_0392_T2_WES_1) from CMI case PCProject_0392, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.6 years (23,968 days).
Specimen PCProject_0392_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd98741a-ff39-4809-ae94-b47264b0a7e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0392_SALIVA (DNA), aliquot PCProject_0392_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/505d6443-b558-455d-9ac6-9adc139b8ce8

The open-access MAF lists 54 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 9, Intron 7, 5'UTR 4, 3'UTR 3, Nonsense Mutation 2, 3'Flank 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS15 | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs564922366; called by muse, mutect2, varscan2
- CD209 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs562144201, COSV52652802; called by muse, mutect2, varscan2
- CNTNAP4 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs755484230, COSV56668176; called by muse, mutect2, varscan2
- CYP4F8 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs769785131, COSV57854562; called by mutect2, varscan2
- FLT3 | c.2957C>T p.P986L | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs587778369, COSV54047766, COSV54049596; ClinVar: not provided; called by muse, mutect2, varscan2
- GOLPH3 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as rs376077685; called by mutect2, varscan2
- KNDC1 | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 118/772 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs896116405; called by muse, mutect2, varscan2
- LSM7 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs772477406; called by muse, mutect2, varscan2
- MUC19 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.024); catalogued as rs903099213; called by muse, mutect2, varscan2
- PARG | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 26/516 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV71279971; called by muse, mutect2
- PLCG1 | c.3848G>A p.R1283Q (on ENST00000373271 / NM_182811.2; = p.R1284Q on NM_002660.3) | Missense Mutation (SNP) | VAF 23/303 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1229586399, COSV99718893; called by muse, mutect2
- SLFN5 | c.258A>C p.L86F | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as rs755336486; called by muse, varscan2
- CACNG8 | c.694C>A p.R232S | Missense Mutation (SNP) | VAF 666/1821 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- CTNND1 | c.1265dup p.E423Gfs*18 | Frame Shift Ins (INS) | VAF 22/132 reads (17%) | called by pindel, varscan2
- DCHS2 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 49/400 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH6 | c.4950G>T p.K1650N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FGF20 | c.299T>G p.F100C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FMN2 | c.3930T>A p.S1310R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2
- GSDMC | c.716A>G p.Q239R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.146); called by muse, mutect2
- LIN54 | c.1346A>T p.N449I | Missense Mutation (SNP) | VAF 56/418 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- NFATC2 | c.2481G>C p.E827D | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PLEKHG4B | c.2359C>T p.P787S (on ENST00000283426; = p.P1143S on NM_052909.5) | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RCVRN | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | called by muse, mutect2, varscan2
- RPS6KA3 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2
- SYT8 | c.97A>C p.I33L | Missense Mutation (SNP) | VAF 53/366 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP30 | c.712G>C p.G238R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF236 | c.3005G>T p.R1002L | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF382 | c.1609G>C p.V537L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, varscan2
- EPHB1 | c.1644C>T p.A548= | Silent (SNP) | VAF 51/502 reads (10%) | catalogued as rs761709703, COSV67664099; called by muse, mutect2, varscan2
- HS3ST2 | c.648G>A p.T216= | Silent (SNP) | VAF 59/280 reads (21%) | catalogued as rs771188795, COSV54462347; called by muse, varscan2
- KBTBD12 | c.843C>T p.G281= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, varscan2
- MYO16 | c.1239T>C p.N413= | Silent (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- OR10K1 | c.171T>C p.T57= | Silent (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.5514G>T p.L1838= | Silent (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- RSBN1 | c.300G>A p.R100= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- SLITRK3 | c.2451G>A p.E817= | Silent (SNP) | VAF 40/284 reads (14%) | called by muse, mutect2, varscan2
- SPNS2 | c.1329T>C p.T443= | Silent (SNP) | VAF 69/460 reads (15%) | called by muse, mutect2, varscan2
- C4BPB | c.410-1087G>A | Intron (SNP) | VAF 14/94 reads (15%) | catalogued as rs1193848258; called by muse, varscan2
- CCDC65 | chr12:48925165 C>T | 3'Flank (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- FMO5 | c.-2C>G | 5'UTR (SNP) | VAF 15/62 reads (24%) | called by muse, varscan2
- GP6 | c.*617T>C | 3'UTR (SNP) | VAF 26/545 reads (5%) | called by muse, mutect2
- HFE | c.*2177A>G | 3'UTR (SNP) | VAF 8/59 reads (14%) | catalogued as rs1460397415; called by muse, varscan2
- INTS1 | c.-34C>G | 5'UTR (SNP) | VAF 33/327 reads (10%) | called by muse, mutect2, varscan2
- OR52A4P | chr11:5120989 A>G | 3'Flank (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- PON3 | c.-12C>T | 5'UTR (SNP) | VAF 73/657 reads (11%) | called by muse, mutect2, varscan2
- PRKCG | c.-290G>T | 5'UTR (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 10/102 reads (10%) | catalogued as rs910081914; called by muse, mutect2
- SGF29 | c.225-425T>C | Intron (SNP) | VAF 14/96 reads (15%) | catalogued as rs1302420508; called by muse, varscan2
- SLC2A11 | c.984+138G>T | Intron (SNP) | VAF 9/52 reads (17%) | catalogued as rs1303766875; called by muse, mutect2
- TCP11L1 | c.297-412A>C | Intron (SNP) | VAF 8/54 reads (15%) | catalogued as rs1192847305; called by muse, mutect2
- TPM3 | chr1:154193715 C>T | 5'Flank (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- TYK2 | c.194-1368T>C | Intron (SNP) | VAF 18/96 reads (19%) | catalogued as rs1386730107; called by muse, mutect2, varscan2
- XIAP | c.*5291A>T | 3'UTR (SNP) | VAF 16/124 reads (13%) | called by muse, varscan2
- XPO5 | c.2678-356T>C | Intron (SNP) | VAF 12/166 reads (7%) | catalogued as rs1242378776, COSV54830476; called by muse, mutect2
